Surgical pathology report (de-identified scan), TCGA case TCGA-YL-A8HL, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site PROCURE Biobank, specimen TCGA-YL-A8HL-01A (Primary Tumor).

[page 1 of 2]
PROSTATE AND PELVIC/OBTURATOR LYMPH NODES; RADICAL PROSTATECTOMY:

HISTOLOGIC TYPE

ACINAR ADENOCARCINOMA

HISTOLOGIC GRADE (PRIMARY PATTERN+SECONDARY PATTERN = GLEASON SCORE):

4 + 5 = 9

TERTIARY PATTERN NOT PRESENT

PERCENTAGE OF DIFFERENT GLEASON PATTERNS

Not described

TUMOR LOCATION

APEX

MID

BASE

ANTERIOR

RIGHT

LEFT

POSTERIOR

RIGHT

LEFT

EXTRA-PROSTATIC EXTENSION

PRESENT

NON-FOCAL

SITE OF EXTRA-PROSTATIC EXTENSION

MID

POSTERIOR

RIGHT

SEMINAL VESICAL INVASION

PRESENT

RIGHT

SURGICAL MARGINS

INVOLVED BY INVASIVE CARCINOMA

APEX

MID

BASE

BLADDER NECK

ANTERIOR

RIGHT

POSTERIOR

RIGHT

NATURE OF POSITIVE MARGINS

INDETERMINATE

EXTENT OF POSITIVE MARGINS

MULTIFOCAL

GLEASON GRADE OF CARCINOMA PRESENT AT THE POSITIVE MARGINS

Not described

LYMPHOVASCULAR INVASION

Not described

PERINEURAL INVASION

PRESENT

TUMOR VOLUME

PROPORTION OF PROSTATE INVOLVED BY CARCINOMA: 75%

TREATMENT EFFECT ON CARCINOMA

NOT APPLICABLE

LYMPH NODES

RIGHT PELVIC

NUMBER OF NODES IDENTIFIED: 2

NUMBER OF NODES INVOLVED BY METASTASIS: 0

LEFT PELVIC

NUMBER OF NODES IDENTIFIED: 3

NUMBER OF NODES INVOLVED BY METASTASIS: 1

NUMBER OF NODES IDENTIFIED: 3

NUMBER OF NODES INVOLVED BY METASTASIS: 1

*ICD-O-3
Adenocarcinoma, acinar
8140/3
Site: Prostate NOS
C61.9
W11/29/13*

[page 2 of 2]
DIAMETER OF LARGEST LYMPH NODE METASTASIS: __30__MM
PATHOLOGICAL STAGING

pT3b
pN1
pMX
*COMMENT(S)

Source: NCI Genomic Data Commons file d06c8bc1-96c6-4747-8e81-b7e9960d1412 (TCGA-YL-A8HL.0C91388C-CCC6-4BBD-B13A-E543A8FC2E5F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).